Somatic mutation profile of tumor specimen ALCH-B1Y9-TTP1-A (aliquot ALCH-B1Y9-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1Y9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen ALCH-B1Y9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43025874-a6e9-4343-b2db-5e9ea733968d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1Y9-NB1-A (Blood Derived Normal), aliquot ALCH-B1Y9-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5939b51b-d9c8-463c-9912-408234f94b11

The open-access MAF lists 425 somatic variants for this specimen: 297 protein-altering or splice-affecting, 79 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 79, Intron 25, Nonsense Mutation 16, RNA 10, Frame Shift Del 9, 5'UTR 5, 3'UTR 5, Splice Site 3, 3'Flank 3, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 23/192 reads (12%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 8/184 reads (4%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2
- ACSBG1 | c.509G>T p.W170L | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1228195428; called by muse, mutect2
- ACTRT1 | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1330623592, COSV64419219; called by muse, varscan2
- ADAMTS12 | c.266A>T p.D89V | Missense Mutation (SNP) | VAF 45/466 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs1025655187; called by muse, mutect2
- ADGRE2 | c.2281T>A p.Y761N | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1202912647; called by muse, mutect2
- ADGRG4 | c.6533T>G p.L2178R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV54950125; called by muse, varscan2
- AKAP3 | c.2549T>A p.M850K | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV50537636; called by muse, mutect2
- AKAP6 | c.3862G>T p.V1288L | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747671412; called by muse, mutect2, varscan2
- AKT3 | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99793830, COSV99794426; called by muse, varscan2
- ARHGAP35 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68330957; called by muse, mutect2, varscan2
- ATP10D | c.4044G>C p.K1348N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as COSV56698054; called by muse, mutect2
- CALCA | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 104/524 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as rs1304418762, COSV100524038; called by muse, mutect2, varscan2
- CAMK2A | c.1120G>A p.D374N (on ENST00000348628 / NM_171825.2; = p.D385N on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.183); catalogued as COSV62245757, COSV62246315; called by muse, mutect2
- CAMTA1 | c.3749C>T p.P1250L | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1383156111; called by muse, mutect2
- CASD1 | c.1738C>T p.L580F | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs746099416, COSV51971572; called by muse, varscan2
- CDC37 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs780606412, COSV55768508; called by muse, mutect2
- CDH10 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.014); catalogued as COSV52582623; called by muse, varscan2
- CDH8 | c.1915G>A p.V639M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100181123; called by muse, mutect2
- CDON | c.2543C>T p.T848M | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753364775; called by muse, mutect2, varscan2
- CEP89 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 21/218 reads (10%) | catalogued as rs770853408; called by muse, mutect2, varscan2
- CFAP57 | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV65264279; called by muse, mutect2, varscan2
- CLCN1 | c.1325G>T p.S442I | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV58372975; called by muse, mutect2
- CLRN2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs201748212, COSV72512547; called by muse, mutect2, varscan2
- COL11A1 | c.2792del p.G931Dfs*51 | Frame Shift Del (DEL) | VAF 19/180 reads (11%) | catalogued as COSV62195668; called by mutect2, pindel, varscan2
- CPNE4 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV101456723; called by muse, mutect2
- CR1 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as rs1357020474; called by muse, mutect2
- CSMD3 | c.4710G>T p.Q1570H (on ENST00000297405 / NM_001363185.1; = p.Q1466H on NM_052900.3) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV52298115; called by muse, mutect2
- CYP11B2 | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 34/592 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV59997564; called by muse, mutect2
- DNAH5 | c.12111G>T p.E4037D | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as COSV54226072; called by muse, mutect2, varscan2
- EGF | c.3448G>T p.V1150L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs552731350; called by muse, mutect2
- EPN1 | c.1492G>T p.A498S (on ENST00000270460 / NM_001321263.1; = p.A472S on NM_013333.3) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV50047848; called by muse, mutect2
- ERICH3 | c.4126T>A p.S1376T | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs1160966464; called by muse, mutect2, varscan2
- FAM47B | c.1091G>A p.C364Y | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs898028646; called by muse, mutect2, varscan2
- FER | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | catalogued as COSV55295977; called by muse, mutect2
- FRMPD1 | c.2992G>T p.G998W | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as COSV100899616; called by muse, varscan2
- GABRA4 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51921709, COSV51923536; called by muse, mutect2, varscan2
- GLOD5 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.576); catalogued as rs782546723; called by muse, mutect2
- GLYATL1 | c.722C>G p.T241R (on ENST00000317391 / NM_001354699.1; = p.T272R on NM_080661.4) | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV104397133; called by muse, mutect2
- GOLGA4 | c.3641C>T p.A1214V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs141111369, COSV62710470; called by muse, mutect2, varscan2
- GRAMD1A | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.082); catalogued as COSV58767538; called by muse, mutect2, varscan2
- H2AC8 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as COSV55127301; called by muse, mutect2
- HCN2 | c.1192T>A p.C398S | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV99242091; called by muse, mutect2, varscan2
- HCN3 | c.2250G>T p.R750S | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1416424368; called by muse, mutect2, varscan2
- IGDCC3 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752536685; called by muse, mutect2
- KCTD8 | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1240066107; called by muse, mutect2
- KDR | c.3413C>A p.T1138N | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV55767699; called by muse, mutect2, varscan2
- KMT2B | c.1084G>T p.D362Y | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs758860377; called by muse, mutect2, varscan2
- LRRC63 | c.233G>C p.C78S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs898249018; called by muse, mutect2, varscan2
- MACF1 | c.15757G>C p.E5253Q (on ENST00000372915; = p.E3186Q on NM_012090.5) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as rs571511038; called by muse, mutect2, varscan2
- MAFB | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.705); catalogued as COSV100965034, COSV100965069; called by muse, mutect2
- MAGEB3 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.049); catalogued as rs761710997, COSV100854844; called by muse, mutect2, varscan2
- MUC2 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs370050240; called by muse, mutect2, varscan2
- NFKB1 | c.757G>T p.V253L (on ENST00000394820 / NM_001382627.1; = p.V254L on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.473); catalogued as rs777489019; called by muse, mutect2
- NLRP13 | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs562148345; called by muse, mutect2, varscan2
- NUP210 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 30/276 reads (11%) | catalogued as COSV54406217, COSV99596374; called by muse, varscan2
- OR6N1 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100625113; called by muse, varscan2
- OR7D4 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV58072916; called by muse, mutect2
- PCDHA11 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 87/639 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as COSV56498827; called by muse, mutect2, varscan2
- PCDHA2 | c.213C>A p.H71Q | Missense Mutation (SNP) | VAF 108/856 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV65370610; called by muse, mutect2, varscan2
- PCDHB4 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.392); catalogued as COSV52019541; called by muse, mutect2, varscan2
- PCNX2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs989007091, COSV99268527; called by muse, varscan2
- PDPK1 | c.1588G>C p.G530R | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.429); catalogued as COSV51912351; called by muse, mutect2
- PRR23B | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV61493835; called by muse, mutect2, varscan2
- PRUNE2 | c.1642A>T p.N548Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV65049211; called by muse, mutect2, varscan2
- PTPRC | c.2133C>A p.S711R | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61421213; called by muse, mutect2, varscan2
- RTL4 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV61207222; called by muse, mutect2, varscan2
- SHANK1 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV53254150; called by muse, mutect2
- SHANK3 | c.4432G>C p.G1478R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1244112596; called by muse, mutect2
- SLC24A5 | c.384A>G p.L128= | Splice Region (SNP) | VAF 12/146 reads (8%) | catalogued as COSV58319150; called by muse, mutect2
- SPATA19 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100141079, COSV54484790; called by muse, varscan2
- SRRM2 | c.2073G>T p.R691S | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as COSV57069550; called by muse, mutect2
- STAP2 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1249845343, COSV74070974; called by muse, mutect2
- SYNE2 | c.16234G>T p.A5412S | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs780778956; called by muse, mutect2, varscan2
- TLR3 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as rs775850017; called by muse, mutect2, varscan2
- TMBIM1 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51464668; called by muse, mutect2, varscan2
- TMIGD2 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV56668298; called by muse, mutect2, varscan2
- TPP1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1344527425, CM052838; called by muse, mutect2
- TRIO | c.6442G>T p.V2148L | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.976); catalogued as COSV100711152; called by muse, mutect2, varscan2
- TSC1 | c.2162G>T p.R721L | Missense Mutation (SNP) | VAF 61/366 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53768103; called by muse, mutect2, varscan2
- TSHR | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV99992256; called by muse, mutect2, varscan2
- USH2A | c.12595G>A p.A4199T | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.03); catalogued as rs1364867539, COSV56370596; called by muse, varscan2
- USH2A | c.7114G>C p.D2372H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as rs766071413, COSV100228912; called by muse, mutect2, varscan2
- XKR4 | c.1850G>C p.R617P | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59303886; called by muse, mutect2, varscan2
- ZIC3 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54975287; called by muse, mutect2, varscan2
- ZNF37A | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764109718; called by muse, mutect2, varscan2
- ZNF536 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV62826344, COSV62830641; called by muse, mutect2
- ZSCAN22 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 19/511 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV61638670; called by muse, mutect2
- ZSCAN5A | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV54227503; called by muse, mutect2, varscan2
- ACSM2B | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM23 | c.2498G>T p.*833Lext*17 | Nonstop Mutation (SNP) | VAF 18/176 reads (10%) | called by muse, varscan2
- ADAMTS12 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAMTS19 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3904T>A p.S1302T | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.01); called by muse, mutect2
- ADARB2 | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by mutect2, varscan2
- ADCY7 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- ADGRF3 | c.297G>C p.Q99H (on ENST00000311519 / NM_001145168.1; = p.Q40H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); called by muse, mutect2
- ALK | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.018); called by muse, mutect2
- ANGPTL3 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 44/389 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- B3GNT7 | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BBS12 | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCHE | c.257C>G p.A86G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, varscan2
- BST2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); called by muse, mutect2
- CBR1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- CBY2 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CCDC14 | c.164G>T p.R55L (on ENST00000488653; = p.R7L on NM_022757.5) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDAN1 | c.708G>A p.W236* | Nonsense Mutation (SNP) | VAF 19/294 reads (6%) | called by muse, mutect2
- CDH20 | c.445T>A p.S149T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDK13 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CELSR1 | c.8168T>A p.L2723Q | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2
- CELSR2 | c.8303G>A p.G2768E | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.146); called by muse, mutect2
- CENPJ | c.3956G>T p.R1319I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP192 | c.2743A>G p.I915V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by mutect2, varscan2
- CLVS2 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE4 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CSGALNACT1 | c.517A>G p.R173G | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CTNNA3 | c.1545G>T p.L515F | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL5 | c.1996T>A p.F666I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CYBRD1 | c.543del p.K181Nfs*2 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- DCAF12L1 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DCP1B | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 30/554 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2
- DGKB | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- DHX36 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DLGAP3 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DMD | c.7093G>T p.V2365F | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, varscan2
- DNAH5 | c.6935G>T p.W2312L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DNASE2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- DQX1 | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, varscan2
- EBLN1 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDEM1 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ELAPOR2 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ETV5 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- FAM47C | c.2228C>A p.P743H | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FAT1 | c.4030G>T p.E1344* | Nonsense Mutation (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- FAT4 | c.11626G>A p.G3876S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT4 | c.11627G>T p.G3876V | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXO40 | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCRL1 | c.183G>T p.L61F | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, varscan2
- FGB | c.1421G>A p.W474* | Nonsense Mutation (SNP) | VAF 17/266 reads (6%) | called by muse, mutect2
- FMNL2 | c.50A>G p.H17R | Missense Mutation (SNP) | VAF 48/481 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GAS7 | c.407G>T p.G136V (on ENST00000432992 / NM_201433.2; = p.G76V on NM_201432.2) | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); called by muse, mutect2
- GCN1 | c.7084G>A p.G2362R | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- GOPC | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- GREB1 | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN1 | c.1772T>A p.V591E | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, varscan2
- GRIN2A | c.2484G>T p.M828I | Missense Mutation (SNP) | VAF 35/714 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- H2BC5 | c.78C>G p.D26E | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.203); called by muse, mutect2
- HACE1 | c.931A>T p.S311C | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- HEATR5A | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMGN2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, varscan2
- HMOX2 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- IGF1R | c.2096G>C p.C699S | Missense Mutation (SNP) | VAF 56/551 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- IGF2BP2 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 129/503 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL12RB1 | c.1898A>T p.E633V | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.103); called by muse, mutect2
- INF2 | c.1189G>C p.V397L | Missense Mutation (SNP) | VAF 117/657 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INHBC | c.544del p.L182* | Frame Shift Del (DEL) | VAF 23/159 reads (14%) | called by mutect2, pindel, varscan2
- IRX2 | c.167C>A p.A56E | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2
- ITM2A | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIAA0753 | c.1561G>C p.E521Q | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.958); called by muse, mutect2
- KLF17 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP10-10 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- LGALS16 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- LHPP | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- LIPC | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 25/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- LRP2 | c.10679G>T p.C3560F | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYST | c.6351A>T p.Q2117H | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, varscan2
- MACF1 | c.14620G>A p.E4874K (on ENST00000372915; = p.E2807K on NM_012090.5) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- MACF1 | c.14773G>C p.E4925Q (on ENST00000372915; = p.E2858Q on NM_012090.5) | Missense Mutation (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- MACF1 | c.14982G>C p.Q4994H (on ENST00000372915; = p.Q2927H on NM_012090.5) | Missense Mutation (SNP) | VAF 46/197 reads (23%) | called by muse, varscan2
- MACF1 | c.15127G>T p.A5043S (on ENST00000372915; = p.A2976S on NM_012090.5) | Missense Mutation (SNP) | VAF 43/218 reads (20%) | called by muse, mutect2, varscan2
- MAK | c.14C>A p.T5K | Missense Mutation (SNP) | VAF 38/459 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.241); called by muse, mutect2
- METTL11B | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 94/462 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- MFN1 | c.1224+1G>A p.X408_splice | Splice Site (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2
- MGA | c.3253A>G p.R1085G | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- MRAS | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MUC16 | c.25523del p.G8508Vfs*29 | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | called by mutect2, pindel
- MUC17 | c.3344G>C p.S1115T | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC19 | c.75T>A p.C25* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2
- MYH13 | c.4178C>A p.A1393D | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYLK4 | c.1092C>G p.H364Q | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, varscan2
- MYT1L | c.3014G>A p.C1005Y | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NADSYN1 | c.1358C>A p.A453D | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- NCAN | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- NLRP14 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NOL4L | c.1137del p.T380Pfs*68 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- NR1I2 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OBSCN | c.8924G>T p.S2975I | Missense Mutation (SNP) | VAF 48/428 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR1G1 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, varscan2
- OR4K14 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- OR4X1 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR5H6 | c.685del p.T229Lfs*14 (on ENST00000642105; = p.T213Lfs*14 on NM_001005479.2) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- OR5K2 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OTOF | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 73/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC1L | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PBXIP1 | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 103/438 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDH17 | c.538G>C p.G180R | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PCDHA7 | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCNT | c.8484G>C p.K2828N | Missense Mutation (SNP) | VAF 13/351 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2
- PDE1C | c.1895C>A p.T632K | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE5A | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHKB | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- PIK3C3 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAT | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCH2 | c.3200C>A p.A1067E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLCXD2 | c.368A>T p.D123V | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLEC | c.5209C>T p.H1737Y (on ENST00000322810 / NM_201380.4; = p.H1627Y on NM_000445.5) | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); called by muse, mutect2
- POGZ | c.2580G>T p.Q860H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- POTEF | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 48/967 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2
- PPIAL4C | c.293del p.L98Cfs*35 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, varscan2
- PPM1G | c.290_301del p.A97_I101delinsV | In Frame Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel
- PPM1N | c.427G>C p.A143P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRCC | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PRCC | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PRDM13 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRKCZ | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRUNE2 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PSD4 | c.1584G>C p.E528D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- PTPRR | c.638T>A p.L213* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | called by muse, varscan2
- PXYLP1 | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); called by muse, mutect2
- RALGPS2 | c.1326-7A>T | Splice Region (SNP) | VAF 15/75 reads (20%) | called by muse, varscan2
- RAP1GAP2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RBFOX2 | c.997A>G p.T333A (on ENST00000438146 / NM_001349995.2; = p.T259A on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- RBM20 | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- RELN | c.7486T>C p.C2496R | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RGPD4 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.18); called by muse, mutect2
- RNF157 | c.1290A>T p.K430N | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RNF6 | c.1012A>T p.R338* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- ROBO4 | c.2047C>A p.Q683K | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- RP1 | c.5753G>C p.C1918S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RP9 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 32/205 reads (16%) | called by muse, varscan2
- RPL13A | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 14/379 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); called by muse, mutect2
- RPL21 | c.375G>T p.W125C | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPN2 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); called by muse, mutect2
- RPUSD3 | c.455G>C p.S152T | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RUFY4 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAFB | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2
- SALL3 | c.2952G>T p.K984N | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SENP7 | c.2049T>A p.C683* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | called by muse, varscan2
- SGCE | c.1114G>T p.A372S (on ENST00000647096; = p.A336S on NM_003919.3) | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SH3GL2 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SIGLEC6 | c.1147A>G p.N383D | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- SIM1 | c.1456A>T p.R486W | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC15A3 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.607); called by muse, mutect2
- SLC17A8 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC20A1 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A3 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- SNCAIP | c.1229C>A p.A410D | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SND1 | c.2667+1G>C p.X889_splice | Splice Site (SNP) | VAF 17/304 reads (6%) | called by muse, mutect2
- SNX31 | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT tolerated (0.65); called by muse, varscan2
- SOX14 | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA7 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPSB4 | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SREK1 | c.1466A>T p.Q489L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- STAB1 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 37/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAB2 | c.4157G>T p.C1386F | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STXBP5L | c.2047A>T p.R683* | Nonsense Mutation (SNP) | VAF 17/203 reads (8%) | called by muse, mutect2
- TBC1D31 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, varscan2
- TBC1D32 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TCTE1 | c.1080C>G p.H360Q | Missense Mutation (SNP) | VAF 74/593 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2
- TCTE1 | c.1078C>A p.H360N | Missense Mutation (SNP) | VAF 70/578 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2
- TF | c.1468A>T p.I490F | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TIGD5 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TJP1 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- TM4SF1 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- TMEM132E | c.2241C>A p.D747E (on ENST00000321639; = p.D837E on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.139); called by muse, mutect2
- TNNI3K | c.1917C>A p.C639* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- TNR | c.968G>T p.C323F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TOMM70 | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, varscan2
- TRAV12-2 | c.206T>C p.M69T | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- TRIM49B | c.1190T>A p.L397H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- TRIM64B | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TUBB4A | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNC5D | c.2347del p.R783Gfs*43 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | called by mutect2, pindel, varscan2
- UNC79 | c.3158A>T p.N1053I (on ENST00000393151 / NM_001346218.2; = p.N876I on NM_020818.5) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- UNC79 | c.6229del p.V2077Wfs*36 (on ENST00000393151 / NM_001346218.2; = p.V1900Wfs*36 on NM_020818.5) | Frame Shift Del (DEL) | VAF 24/167 reads (14%) | called by mutect2, pindel, varscan2
- URI1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- USP15 | c.1901G>C p.C634S (on ENST00000280377 / NM_001351159.2; = p.C605S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDFY3 | c.7710G>T p.M2570I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- WDR87 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- WDR97 | c.2707G>A p.D903N | Missense Mutation (SNP) | VAF 81/595 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ZBTB39 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- ZFHX4 | c.7397C>A p.S2466Y | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ZNF133 | c.713G>T p.G238V (on ENST00000316358 / NM_001352454.2; = p.G237V on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF22 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF354C | c.68A>C p.Q23P | Missense Mutation (SNP) | VAF 44/330 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ZNF404 | c.576T>A p.C192* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | called by muse, varscan2
- ZNF414 | c.262A>G p.I88V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ZNF497 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZNF600 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF649 | c.544G>T p.D182Y | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ZNF711 | c.2217G>C p.K739N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, varscan2
- ZNF737 | c.887G>C p.R296P | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ZNF737 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2
- ZNF784 | c.20A>T p.E7V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZUP1 | c.1073G>T p.W358L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZWINT | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA2 | c.7266G>T p.R2422= (on ENST00000614293; = p.R2392= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/364 reads (14%) | catalogued as rs762879252; called by muse, mutect2, varscan2
- ABCC10 | c.2283C>T p.A761= (on ENST00000372530 / NM_001198934.2; = p.A733= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- AKAP4 | c.1233G>T p.L411= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- ANGPT4 | c.1404C>T p.H468= | Silent (SNP) | VAF 40/440 reads (9%) | catalogued as rs367995955; called by muse, mutect2
- ASCL3 | c.354T>C p.H118= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- ASTN1 | c.1938C>A p.R646= | Silent (SNP) | VAF 53/400 reads (13%) | catalogued as COSV99923347; called by muse, mutect2, varscan2
- ATP9B | c.768A>T p.S256= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- BLK | c.591G>T p.S197= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as rs140834602; called by muse, mutect2
- C1QTNF2 | c.360G>T p.R120= (on ENST00000393975; = p.R75= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/357 reads (13%) | called by muse, mutect2, varscan2
- C2CD4B | c.366G>T p.A122= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- C4orf54 | c.2238C>A p.R746= | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- CCDC137 | c.240G>T p.P80= | Silent (SNP) | VAF 27/263 reads (10%) | catalogued as COSV100235704; called by muse, mutect2, varscan2
- CDR1 | c.327G>T p.P109= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV65164056; called by mutect2, varscan2
- CELSR1 | c.8169G>T p.L2723= | Silent (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- CYP11B2 | c.1023C>A p.R341= | Silent (SNP) | VAF 34/590 reads (6%) | called by muse, mutect2
- DHRS2 | c.534A>T p.P178= | Silent (SNP) | VAF 33/308 reads (11%) | catalogued as rs1393218700; called by muse, mutect2, varscan2
- DHX35 | c.1197G>C p.S399= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as COSV52669058; called by muse, mutect2, varscan2
- DNAH1 | c.3372C>T p.P1124= | Silent (SNP) | VAF 34/241 reads (14%) | called by muse, mutect2, varscan2
- EEFSEC | c.384G>C p.A128= | Silent (SNP) | VAF 48/418 reads (11%) | called by muse, mutect2, varscan2
- EIF3A | c.1815G>C p.R605= | Silent (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- ESPL1 | c.2853C>T p.L951= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- ETV5 | c.1089G>A p.Q363= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as COSV100112258; called by muse, varscan2
- FAM47C | c.2229C>A p.P743= | Silent (SNP) | VAF 75/336 reads (22%) | catalogued as COSV63725726; called by muse, mutect2, varscan2
- GOLGA6L7 | c.39G>T p.G13= | Silent (SNP) | VAF 26/283 reads (9%) | called by muse, mutect2
- GRIN2B | c.3633G>T p.G1211= | Silent (SNP) | VAF 10/127 reads (8%) | called by muse, mutect2
- GRIN2B | c.1839G>T p.V613= | Silent (SNP) | VAF 31/408 reads (8%) | called by muse, mutect2
- GRK4 | c.1455G>C p.S485= (on ENST00000398052 / NM_182982.3; = p.S453= on NM_005307.3) | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- HECTD1 | c.6534T>C p.Y2178= | Silent (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- HIVEP3 | c.6690C>T p.S2230= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs141844226; called by muse, mutect2
- IGFBP4 | c.558C>T p.A186= | Silent (SNP) | VAF 38/338 reads (11%) | catalogued as rs1340417200; called by muse, mutect2, varscan2
- ILVBL | c.798C>G p.P266= | Silent (SNP) | VAF 18/239 reads (8%) | called by muse, mutect2
- KATNIP | c.4683C>T p.I1561= | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- KCNS2 | c.1119C>A p.T373= | Silent (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- KMT2B | c.1083G>A p.L361= | Silent (SNP) | VAF 38/321 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.70C>A p.R24= | Silent (SNP) | VAF 80/617 reads (13%) | called by muse, mutect2, varscan2
- MBL2 | c.165C>A p.T55= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV100906366; called by muse, mutect2, varscan2
- MST1R | c.2919G>T p.A973= | Silent (SNP) | VAF 60/404 reads (15%) | called by muse, mutect2, varscan2
- MYH13 | c.4608A>G p.L1536= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs1160082273; called by muse, mutect2, varscan2
- MYH15 | c.1845A>G p.E615= | Silent (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- MYH6 | c.4470C>T p.Y1490= | Silent (SNP) | VAF 94/535 reads (18%) | catalogued as rs727504964, COSV62449157; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2T1 | c.861C>T p.L287= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as COSV100822297; called by muse, mutect2, varscan2
- OR6Q1 | c.81C>T p.L27= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as rs1301261329; called by muse, mutect2
- OR7D4 | c.606C>T p.A202= | Silent (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- PCDH17 | c.2787A>G p.P929= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1219987920; called by mutect2, varscan2
- PCDHB1 | c.126C>A p.G42= | Silent (SNP) | VAF 20/435 reads (5%) | called by muse, mutect2
- PHLDB1 | c.3627C>T p.V1209= | Silent (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- PLCG2 | c.2676G>A p.R892= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs759166545; called by muse, mutect2, varscan2
- PLEKHH1 | c.696A>T p.A232= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2
- PROKR2 | c.60T>C p.H20= | Silent (SNP) | VAF 38/347 reads (11%) | catalogued as rs1210956597; called by muse, mutect2, varscan2
- RIN2 | c.1299A>G p.A433= (on ENST00000255006 / NM_001242581.1; = p.A384= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs1165507485; called by muse, mutect2, varscan2
- RPN1 | c.18C>T p.A6= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs777405053, COSV56191145; called by mutect2, varscan2
- RYR2 | c.9021A>G p.L3007= | Silent (SNP) | VAF 46/284 reads (16%) | catalogued as rs748115355; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD15 | c.108A>G p.E36= | Silent (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2, varscan2
- SERPINA12 | c.1149C>A p.V383= | Silent (SNP) | VAF 26/234 reads (11%) | catalogued as COSV100369738; called by muse, mutect2, varscan2
- SHOC2 | c.828C>T p.L276= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs1278827664; called by muse, varscan2
- SHROOM3 | c.2949G>T p.R983= | Silent (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- SIGLEC1 | c.4581C>A p.L1527= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as COSV52464471; called by muse, mutect2, varscan2
- SLC17A8 | c.201C>T p.C67= | Silent (SNP) | VAF 39/339 reads (12%) | catalogued as COSV100035702; called by muse, mutect2, varscan2
- SLC17A9 | c.264G>T p.G88= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2
- SLC1A2 | c.957A>G p.T319= | Silent (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- SLC26A4 | c.255T>A p.L85= | Silent (SNP) | VAF 66/362 reads (18%) | called by muse, mutect2, varscan2
- SLC6A2 | c.573C>G p.L191= | Silent (SNP) | VAF 41/218 reads (19%) | catalogued as COSV99573584; called by muse, mutect2, varscan2
- SNCAIP | c.1230C>T p.A410= | Silent (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- SYT3 | c.1641C>T p.R547= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as rs1431914047; called by muse, mutect2, varscan2
- TBC1D30 | c.2277C>T p.N759= (on ENST00000542120; = p.N596= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/300 reads (14%) | catalogued as rs564361650; called by muse, mutect2, varscan2
- TENM3 | c.2196C>T p.G732= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as COSV69319862; called by muse, mutect2, varscan2
- TFAP2D | c.252C>A p.A84= | Silent (SNP) | VAF 19/192 reads (10%) | catalogued as COSV50408070, COSV50412073; called by muse, mutect2, varscan2
- TFAP2D | c.744C>T p.L248= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- TMCC3 | c.625C>T p.L209= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs1249943499; called by muse, mutect2
- TPST1 | c.42G>T p.L14= | Silent (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1533G>T p.T511= | Silent (SNP) | VAF 104/648 reads (16%) | catalogued as rs750274973; called by muse, mutect2, varscan2
- UCKL1 | c.1563C>G p.G521= | Silent (SNP) | VAF 22/230 reads (10%) | called by muse, mutect2
- WDR90 | c.1884C>T p.S628= | Silent (SNP) | VAF 10/135 reads (7%) | called by muse, mutect2
- ZFP36L2 | c.756C>T p.P252= | Silent (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- ZNF28 | c.39G>T p.V13= | Silent (SNP) | VAF 28/158 reads (18%) | called by muse, varscan2
- ZNF385D | c.1113T>A p.L371= | Silent (SNP) | VAF 34/600 reads (6%) | called by muse, mutect2
- ZNF584 | c.861G>T p.R287= | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- ZNF646 | c.4482C>T p.H1494= | Silent (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- ZNF716 | c.1008C>T p.S336= | Silent (SNP) | VAF 37/222 reads (17%) | called by muse, varscan2
- AC005863.1 | n.173C>T | RNA (SNP) | VAF 43/299 reads (14%) | called by muse, mutect2, varscan2
- AC011487.2 | n.1080T>G | RNA (SNP) | VAF 10/229 reads (4%) | called by muse, mutect2
- AC015911.9 | n.639G>C | RNA (SNP) | VAF 17/127 reads (13%) | catalogued as COSV63140365; called by muse, mutect2, varscan2
- AFMID | c.468-35G>T | Intron (SNP) | VAF 93/412 reads (23%) | called by muse, mutect2, varscan2
- ATP10B | c.1381+78G>T | Intron (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- BIRC8 | n.1724C>A | RNA (SNP) | VAF 8/23 reads (35%) | catalogued as COSV58844919; called by muse, mutect2, varscan2
- CCDC24 | c.-37C>A | 5'UTR (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- CD1C | c.*73C>A | 3'UTR (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- COX10 | c.-18G>T | 5'UTR (SNP) | VAF 43/334 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.6245-10299A>C | Intron (SNP) | VAF 14/100 reads (14%) | called by muse, varscan2
- DCDC2 | c.923-40C>A | Intron (SNP) | VAF 8/172 reads (5%) | catalogued as COSV65829498; called by muse, mutect2
- DOK3 | chr5:177503091 del G | 3'Flank (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- EGFLAM | c.-52C>A | 5'UTR (SNP) | VAF 71/292 reads (24%) | called by muse, mutect2, varscan2
- EPHA6 | c.2784+8137G>C | Intron (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- GRHPR | c.734+257G>A | Intron (SNP) | VAF 27/264 reads (10%) | catalogued as rs756505435; called by muse, mutect2, varscan2
- GRIK5 | c.2514+997G>A | Intron (SNP) | VAF 18/276 reads (7%) | called by muse, mutect2
- GRK5 | c.148+7208del | Intron (DEL) | VAF 28/251 reads (11%) | called by mutect2, pindel, varscan2
- GUCY2EP | n.1683C>T | RNA (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2, varscan2
- HBB | c.315+11G>T | Intron (SNP) | VAF 41/256 reads (16%) | catalogued as COSV58942374; called by muse, mutect2, varscan2
- HBB | c.315+10T>A | Intron (SNP) | VAF 42/264 reads (16%) | called by muse, mutect2, varscan2
- HOXA4 | c.-15G>T | 5'UTR (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- HSPA1B | chr6:31835156 G>A | 3'Flank (SNP) | VAF 12/247 reads (5%) | catalogued as rs1562384872; called by muse, mutect2
- ISOC2 | c.*38C>T | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- LENG8 | c.*2819C>T | 3'UTR (SNP) | VAF 26/313 reads (8%) | catalogued as rs1200993088; called by muse, mutect2
- LILRB2 | c.35-22C>A | Intron (SNP) | VAF 49/276 reads (18%) | called by muse, mutect2, varscan2
- LINC01517 | n.579G>T | RNA (SNP) | VAF 38/454 reads (8%) | called by muse, mutect2
- LYRM4 | c.208-29242A>G | Intron (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- MET | c.2265-52C>T | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
- MIR133A2 | chr20:62565068 G>T | 3'Flank (SNP) | VAF 47/231 reads (20%) | catalogued as rs781934657; called by muse, mutect2, varscan2
- MIR6859-4 | chr16:17405 A>T | 5'Flank (SNP) | VAF 43/440 reads (10%) | called by muse, varscan2
- NLRP3 | c.2664-44G>T | Intron (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- NRBP1 | c.661+514C>T | Intron (SNP) | VAF 21/217 reads (10%) | called by muse, mutect2
- OOSP2 | c.348-223T>C | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- OR10D1P | n.435G>A | RNA (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- PAGE5 | c.-18G>A | 5'UTR (SNP) | VAF 49/228 reads (21%) | catalogued as rs1304273412, COSV99215869; called by muse, mutect2, varscan2
- PDE4B | c.281+74193C>A | Intron (SNP) | VAF 36/195 reads (18%) | called by muse, mutect2, varscan2
- PPP5C | c.634-80C>A | Intron (SNP) | VAF 123/668 reads (18%) | called by muse, mutect2, varscan2
- PREX2 | c.3146+1329T>G | Intron (SNP) | VAF 8/66 reads (12%) | called by muse, varscan2
- RRH | c.*14G>A | 3'UTR (SNP) | VAF 16/124 reads (13%) | catalogued as rs758711697, COSV58492856; called by muse, varscan2
- SPATA31D5P | n.589del | RNA (DEL) | VAF 36/295 reads (12%) | called by mutect2, pindel, varscan2
- SPEF2 | c.4448-2445G>T | Intron (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.14232C>T | RNA (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2
- TEPP | c.688-50G>T | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- TRIM25 | c.*881G>A | 3'UTR (SNP) | VAF 235/862 reads (27%) | called by muse, mutect2, varscan2
- TRIM67 | c.1045-12207C>A | Intron (SNP) | VAF 94/493 reads (19%) | called by muse, mutect2, varscan2
- TUBB7P | n.447C>T | RNA (SNP) | VAF 70/352 reads (20%) | catalogued as rs1480769651; called by muse, mutect2, varscan2
- UIMC1 | c.1598-7860T>A | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- UNC5A | c.293-2425G>T | Intron (SNP) | VAF 23/161 reads (14%) | catalogued as rs543842855; called by muse, mutect2
- WNT7B | c.71+4473G>C | Intron (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
